Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4718, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4718-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: LEFT KIDNEY, PROXIMAL URETER, AND ADRENAL GLAND, LAPAROSCOPIC RADICAL NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FURHMAN NUCLEAR GRADE IS 2/4.
- C. CARCINOMA MEASURES 8 CM IN GREATEST DIMENSION AND IS LOCATED IN THE LOWER POLE.
- D. SEPARATE EXTRARENAL SATELLITE TUMOR NODULE, 0.6 CM, LOCATED WITHIN THE LOWER POLE PERIRENAL ADIPOSE TISSUE (See comment).
- E. NO RENAL VEIN TUMOR THROMBUS IS IDENTIFIED.
- F. FOCAL MICROSCOPIC ANGIOLYMPHATIC INVASION IS IDENTIFIED (SLIDE 1K).
- G. ALL SURGICAL MARGINS ARE FREE OF NEOPLASIA.
- H. TNM PATHOLOGIC STAGE: pT3a NX MX (See comment and synoptic report).
- I. BACKGROUND RENAL CORTICAL AND MEDULLARY PARENCHYMA IS UNREMARKABLE.
- J. PORTION OF BENIGN, UNREMARKABLE ADRENAL GLAND.

PART 2: ADRENAL GLAND, LEFT, ADRENALECTOMY -

- A. BENIGN ADRENAL CORTICAL NODULE, 0.7 CM.
- B. NO EVIDENCE OF NEOPLASIA.

COMMENT:

The main tumor measures 8.0 cm in greatest diameter and is located in the lower pole. There is a physically separate, satellite tumor nodule located in the perirenal adipose tissue opposite the hilum, one millimeter from the main tumor. This nodule measures 0.6 cm in greatest dimension, is well-circumscribed, and is surrounded by fibrosis.

The satellite tumor nodule was entirely submitted for histologic evaluation with multiple deeper levels examined and there is no evidence of a direct connection with the main tumor. There is no histologic evidence of residual lymph node architecture or a vascular wall surrounding the satellite nodule.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE:	Radical nephrectomy
LATERALITY:	Left
TUMOR SITE:	Lower pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 8.0 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor extension into perinephric tissues
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G2
PATHOLOGIC STAGING (pTNM):	pT3a
	pNX
	Number of regional lymph nodes examined: 0
	pMX
MARGINS:	Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Uninvolved by tumor
LYMPHATIC (SMALL VESSEL) INVASION (L):	Present
Comment:	Satellite lower pole perirenal nodule of renal cell carcinoma (see Diagnosis comment field)

Source: NCI Genomic Data Commons file 8d042322-3109-47a6-be89-89524e53409e (TCGA-B0-4718.334244DB-99CF-4222-8F70-34BDD65BB792.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).